Somatic mutation profile of tumor specimen TCGA-BK-A26L-01A (aliquot TCGA-BK-A26L-01A-11D-A272-09) from TCGA case TCGA-BK-A26L, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 71.2 years (26,002 days).
Specimen TCGA-BK-A26L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f114c1b-0bf4-43dc-ad0c-284f07f42d35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BK-A26L-10A (Blood Derived Normal), aliquot TCGA-BK-A26L-10A-01D-A16D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/775f574b-5e24-4c70-8a57-d4a40ca880a0

The open-access MAF lists 72 somatic variants for this specimen: 54 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 16, Intron 2, Nonsense Mutation 2, Splice Site 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1514G>T p.R505L (on ENST00000281708 / NM_001349798.2; = p.R425L on NM_018315.5) | Missense Mutation (SNP) | VAF 23/48 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519896, COSV55901126, COSV55908371, COSV55911517; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 62/190 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.497C>G p.S166* | Nonsense Mutation (SNP) | VAF 41/66 reads (62%) | catalogued as rs1555526101, COSV52661795, COSV52683537, COSV52718793; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTN1 | c.2548C>T p.R850C | Missense Mutation (SNP) | VAF 29/228 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs148344567; called by muse, mutect2, varscan2
- ADARB2 | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 65/132 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs377469652; called by muse, mutect2
- ADGRB2 | c.2228G>A p.R743Q | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as COSV99925561; called by muse, mutect2, varscan2
- ADRA2B | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as rs777594888, COSV101337338; called by muse, mutect2
- ALPL | c.940G>C p.V314L | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV100876139; called by muse, mutect2, varscan2
- AMER1 | c.1343T>C p.L448P | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs141789259, COSV100365171; called by muse, mutect2
- ARHGAP26 | c.1501C>T p.R501W | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50829120; called by muse, mutect2, varscan2
- CALN1 | c.458T>G p.I153S (on ENST00000329008 / NM_001017440.3; = p.I195S on NM_031468.4) | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100204403; called by muse, mutect2, varscan2
- DCC | c.2866A>G p.R956G | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV100497688; called by muse, mutect2, varscan2
- DIO2 | c.182G>T p.R61L | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.965); catalogued as COSV101375807, COSV70445116; called by muse, mutect2, varscan2
- DYTN | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.144); catalogued as COSV101510792; called by muse, mutect2, varscan2
- EZHIP | c.1204C>T p.H402Y | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV100539434; called by muse, mutect2, varscan2
- FOXH1 | c.775G>T p.A259S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100023422; called by muse, mutect2, varscan2
- FSHR | c.601A>C p.S201R | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as COSV100436400; called by muse, mutect2, varscan2
- HDAC8 | c.816T>A p.D272E | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101005241; called by muse, mutect2
- HELZ2 | c.798G>C p.K266N | Missense Mutation (SNP) | VAF 38/231 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100915411; called by muse, mutect2, varscan2
- HTR6 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.23); catalogued as rs149981613; called by muse, mutect2, varscan2
- KCNK2 | c.310T>A p.S104T (on ENST00000444842 / NM_001017425.3; = p.S89T on NM_014217.4) | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV101221762; called by muse, mutect2, varscan2
- KIF3C | c.2354G>T p.R785L | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV99266967; called by muse, mutect2, varscan2
- LARS2 | c.374C>A p.P125H | Missense Mutation (SNP) | VAF 66/137 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99647325; called by muse, mutect2, varscan2
- LRRIQ1 | c.3614T>A p.M1205K | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV101279301; called by muse, mutect2, varscan2
- MAGEA3 | c.751G>T p.V251L | Missense Mutation (SNP) | VAF 171/362 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV64755983; called by muse, mutect2, varscan2
- MAGEC2 | c.257G>T p.S86I | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.928); catalogued as COSV99909352; called by muse, mutect2, varscan2
- MAGEE1 | c.1327G>A p.V443M | Missense Mutation (SNP) | VAF 41/237 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs1556839632, COSV63910460; called by muse, mutect2, varscan2
- ME2 | c.505C>T p.L169F | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100360597, COSV58425335; called by muse, mutect2, varscan2
- MYH7 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 77/204 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as COSV100805612; called by muse, mutect2, varscan2
- MYOCD | c.2458A>G p.M820V | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100590037; called by muse, mutect2, varscan2
- MYRIP | c.333-2A>G p.X111_splice | Splice Site (SNP) | VAF 20/88 reads (23%) | catalogued as COSV100218195; called by muse, mutect2, varscan2
- NPY2R | c.144G>T p.E48D | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV100279403; called by muse, mutect2, varscan2
- PPP2R5D | c.261A>C p.Q87H | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV100028407; called by muse, mutect2
- RIN2 | c.410A>T p.D137V (on ENST00000255006 / NM_001242581.1; = p.D88V on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99656557; called by muse, mutect2, varscan2
- SALL3 | c.2936G>T p.C979F | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV101609914; called by muse, mutect2, varscan2
- SCN9A | c.274A>G p.N92D | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as rs747265095, COSV100311058; called by muse, mutect2, varscan2
- SDK2 | c.4532C>T p.T1511M | Missense Mutation (SNP) | VAF 112/162 reads (69%) | SIFT tolerated (0.05); PolyPhen benign (0.21); catalogued as rs140102684; called by muse, mutect2, varscan2
- SLC25A48 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs746170434, COSV99191925; called by muse, mutect2, varscan2
- SLC39A12 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755814869, COSV66201244, COSV66201612; called by muse, mutect2, varscan2
- SLC7A9 | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 16/79 reads (20%) | catalogued as COSV50084187; called by muse, mutect2, varscan2
- STYXL2 | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776784375, COSV99608457; called by muse, mutect2, varscan2
- THSD4 | c.1133G>A p.C378Y | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs1364571014, COSV99964183; called by muse, mutect2, varscan2
- TRIM23 | c.919C>G p.L307V | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.142); catalogued as rs764699841, COSV99139840; called by muse, mutect2, varscan2
- TTC23 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs760600439, COSV50440936; called by muse, mutect2, varscan2
- UHRF2 | c.2275C>T p.R759C | Missense Mutation (SNP) | VAF 34/484 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs912066578, COSV52793655; called by muse, mutect2
- VGLL3 | c.563C>G p.P188R | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV101051849, COSV67352658; called by muse, mutect2, varscan2
- WDFY3 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99881638; called by muse, mutect2, varscan2
- YTHDC2 | c.1954A>T p.S652C | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV99362823; called by muse, mutect2
- ZGPAT | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs1176701629, COSV58874264; called by muse, mutect2
- ZIM2 | c.1252G>A p.G418S | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as rs1238828956, COSV55648393; called by muse, mutect2, varscan2
- ZNF229 | c.763C>G p.L255V | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.188); catalogued as COSV99349948; called by muse, mutect2, varscan2
- ZNF99 | c.2161A>G p.R721G | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.184); catalogued as COSV101233651; called by muse, mutect2
- MAGEC1 | c.1714dup p.E572Gfs*75 | Frame Shift Ins (INS) | VAF 30/198 reads (15%) | called by mutect2, varscan2
- RB1CC1 | c.633_634del p.H211Qfs*14 | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | called by mutect2, pindel, varscan2
- AP3B2 | c.3207C>T p.S1069= (on ENST00000261722; = p.S1063= on NM_004644.5) | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as rs540715932, COSV55607437; called by muse, mutect2, varscan2
- C15orf39 | c.1044C>G p.A348= | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as COSV100641160; called by muse, mutect2, varscan2
- CDIPT | c.210G>T p.L70= | Silent (SNP) | VAF 36/211 reads (17%) | catalogued as COSV99570086; called by muse, mutect2, varscan2
- CR1L | c.180T>C p.Y60= | Silent (SNP) | VAF 63/190 reads (33%) | catalogued as COSV99686712; called by muse, mutect2, varscan2
- DYNC2I1 | c.2109C>T p.C703= | Silent (SNP) | VAF 21/236 reads (9%) | catalogued as rs146344761, COSV101337593, COSV101337758; called by muse, mutect2
- ESRRA | c.93C>G p.T31= | Silent (SNP) | VAF 64/237 reads (27%) | catalogued as rs200261687, COSV50004576, COSV99134409; called by muse, mutect2, varscan2
- GRID1 | c.1614C>T p.D538= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs1441235817, COSV100021404; called by muse, mutect2, varscan2
- GUCY1A2 | c.900T>C p.N300= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as rs535328414, COSV56489461, COSV99972307; called by muse, mutect2, varscan2
- LAMTOR5 | c.195G>T p.V65= (on ENST00000602318 / NM_001382293.1; = p.V147= on NM_006402.3) | Silent (SNP) | VAF 53/128 reads (41%) | catalogued as COSV99862039; called by muse, mutect2, varscan2
- LCE2D | c.138C>A p.S46= | Silent (SNP) | VAF 28/198 reads (14%) | catalogued as COSV100909514, COSV100909626; called by muse, mutect2, varscan2
- PSME1 | c.12C>T p.L4= | Silent (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- STIMATE-MUSTN1 | c.1113C>T p.F371= | Silent (SNP) | VAF 27/136 reads (20%) | catalogued as rs1367057440, COSV99818798; called by muse, mutect2, varscan2
- SYT2 | c.816C>T p.G272= | Silent (SNP) | VAF 45/110 reads (41%) | catalogued as rs746445612, COSV100937116; called by muse, mutect2, varscan2
- TBL1X | c.1731G>A p.K577= | Silent (SNP) | VAF 20/111 reads (18%) | catalogued as COSV54289338; called by muse, mutect2, varscan2
- WASHC2A | c.3543T>C p.D1181= | Silent (SNP) | VAF 21/256 reads (8%) | called by muse, mutect2
- ZMYM3 | c.561A>T p.P187= | Silent (SNP) | VAF 79/256 reads (31%) | catalogued as COSV100077377; called by muse, mutect2, varscan2
- ATP8A2 | c.1662+59G>A | Intron (SNP) | VAF 130/200 reads (65%) | catalogued as COSV54938762; called by muse, mutect2, varscan2
- LIN7A | c.82+1852A>G | Intron (SNP) | VAF 7/64 reads (11%) | catalogued as COSV99691628; called by muse, mutect2, varscan2
